CPTAC case C3L-02779 — Hematopoietic and reticuloendothelial systems — Myeloid Leukemias (CPTAC-3)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026), part of the Clinical Proteomic Tumor Analysis Consortium (CPTAC). Disease type: Myeloid Leukemias; Primary site: Hematopoietic and reticuloendothelial systems. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/ee230fa2-b736-4609-9693-6893f847b088

Demographics
Sex at birth: male; Race: white; Ethnicity: not hispanic or latino; Year of birth: 1967; Vital status: Alive.

Diagnoses (1)
1. Acute myeloid leukemia, NOS: ICD-O-3 morphology code: 9861/3; Tissue or organ of origin: Hematopoietic system, NOS; Site of resection or biopsy: Hematopoietic system, NOS; Age at diagnosis: 51.6 years (18,858 days); Year of diagnosis: 2018; Days to last known disease status: 1,946 days (5.3 years); Progression or recurrence: no; Days to last follow up: 1,946 days (5.3 years).
   Chemotherapy — whether it was given is not recorded by GDC; Treatment outcome: Complete Response.

Follow-up (1 entry)
- Follow-up contacts recording only the day: day 381, day 777, day 1,123, day 1,526.

Exposures
- Tobacco smoking status: Current Smoker; Cigarettes per day: 20; Alcohol history: Yes; Alcohol intensity: Not Heavy Drinker.

Biospecimens (4 samples)
- Samples C3L-02779-51, C3L-02779-52 (2 with the same recorded description): Sample type: Buccal Cell Normal; Tissue type: Normal; Specimen type: Buccal Cells; Preservation method: Frozen; Freezing method: -80 (unit not recorded by GDC).
- Sample C3L-02779-54: Sample type: Primary Blood Derived Cancer - Peripheral Blood; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Peripheral Whole Blood; Biospecimen anatomic site: Blood; Preservation method: Frozen; Freezing method: -80 (unit not recorded by GDC); Days to sample procurement: 7 days; Method of sample procurement: Blood Draw; Diagnosis pathologically confirmed: Yes. An open-access masked somatic mutation file (MAF) exists for this specimen and lists no variants.
- Sample C3L-02779-56: Sample type: Primary Blood Derived Cancer - Peripheral Blood; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Peripheral Whole Blood; Biospecimen anatomic site: Blood; Preservation method: Frozen; Freezing method: -80 (unit not recorded by GDC); Days to sample procurement: 7 days; Method of sample procurement: Blood Draw; Diagnosis pathologically confirmed: Yes.
